OHSU case 1435 — OHSU-CNL: Philadelphia-Negative Neutrophilic Leukemias (CNL/aCML/MDS/MPNu)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Chronic Myeloproliferative Disorders; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/5fd38b68-d534-45de-a75f-6fe15f0d6c51

Biospecimens (1 sample)
- Sample 3627R: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Fresh.
